Somatic mutation profile of tumor specimen HCM-BROD-0125-C25-01A (aliquot HCM-BROD-0125-C25-01A-11D-A79L-36) from HCMI case HCM-BROD-0125-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 72.9 years (26,629 days).
Specimen HCM-BROD-0125-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b869b6d-bfac-4653-84de-c551fd9f1937.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0125-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0125-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c70975a4-22e2-4330-b09a-a83278c0a6bf

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 24, Silent 13, Nonsense Mutation 3, In Frame Del 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 47/258 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.3046C>T p.R1016* | Nonsense Mutation (SNP) | VAF 186/686 reads (27%) | catalogued as rs759085500, COSV100617298; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.431A>C p.Q144P | Missense Mutation (SNP) | VAF 121/364 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs786203071, CM023462, COSV52661000, COSV52675618, COSV52761562, COSV53080684; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- APBA2 | c.2122G>A p.V708M | Missense Mutation (SNP) | VAF 114/425 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs538291011, COSV68790237; called by muse, mutect2, varscan2
- C3 | c.2851C>T p.R951C | Missense Mutation (SNP) | VAF 98/461 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as rs780884558, COSV55568795; called by muse, mutect2, varscan2
- CAD | c.6086G>A p.G2029E | Missense Mutation (SNP) | VAF 57/318 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1020986533; called by muse, mutect2, varscan2
- COLEC10 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100250981; called by muse, mutect2, varscan2
- GRIA4 | c.286G>C p.G96R | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56905172; called by muse, mutect2, varscan2
- L3MBTL1 | c.414del p.S139Afs*9 (on ENST00000418998 / NM_001377303.1; = p.S49Afs*9 on NM_015478.7) | Frame Shift Del (DEL) | VAF 110/563 reads (20%) | catalogued as COSV100917301; called by mutect2, pindel, varscan2
- NRXN3 | c.2420G>C p.R807P (on ENST00000335750 / NM_001330195.2; = p.R434P on NM_004796.6) | Missense Mutation (SNP) | VAF 95/289 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59758617; called by muse, mutect2, varscan2
- NUP155 | c.881G>A p.R294Q (on ENST00000231498 / NM_153485.3; = p.R235Q on NM_004298.4) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs201036380, COSV104371410; called by muse, varscan2
- PCDHGA3 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 114/592 reads (19%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as COSV53923997; called by muse, mutect2, varscan2
- PPM1F | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 97/328 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1474170519; called by muse, mutect2, varscan2
- PSD2 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 131/637 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs764425844, COSV51197172; called by muse, mutect2, varscan2
- ZNF440 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 86/343 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as rs530490353, COSV58371088; called by muse, mutect2, varscan2
- ACRBP | c.944+6G>C | Splice Region (SNP) | VAF 108/402 reads (27%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.1603A>T p.I535L (on ENST00000310343 / NM_001378025.1; = p.I186L on NM_014715.4) | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- B3GALT5 | c.56T>G p.L19R | Missense Mutation (SNP) | VAF 89/298 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- ELMO2 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 37/381 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); called by muse, mutect2
- FRMD8 | c.92A>G p.D31G | Missense Mutation (SNP) | VAF 56/360 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HOXD9 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 25/333 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.238); called by muse, mutect2
- IRX2 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 198/576 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC2 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 76/338 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- NCR3LG1 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 113/352 reads (32%) | called by muse, mutect2, varscan2
- OR52E6 | c.282A>G p.I94M | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- SATB1 | c.88A>T p.I30F | Missense Mutation (SNP) | VAF 91/413 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TAF4 | c.2510_2512del p.V837del | In Frame Del (DEL) | VAF 55/329 reads (17%) | called by mutect2, pindel, varscan2
- TMEM38A | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 91/430 reads (21%) | called by muse, mutect2, varscan2
- TRIM62 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 53/692 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.079); called by muse, mutect2
- ZC3H6 | c.2467G>A p.D823N | Missense Mutation (SNP) | VAF 82/411 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ZNF865 | c.1417_1431del p.P473_A477del | In Frame Del (DEL) | VAF 66/398 reads (17%) | called by mutect2, pindel
- CLDN8 | c.264C>T p.S88= | Silent (SNP) | VAF 89/305 reads (29%) | catalogued as rs372970119, COSV99729682; called by muse, mutect2, varscan2
- CSMD2 | c.3972C>T p.D1324= | Silent (SNP) | VAF 88/353 reads (25%) | catalogued as rs769259843; called by muse, mutect2, varscan2
- DHX38 | c.3270C>T p.Y1090= | Silent (SNP) | VAF 80/332 reads (24%) | catalogued as rs111685951; called by muse, mutect2, varscan2
- DIP2C | c.900C>T p.A300= | Silent (SNP) | VAF 98/399 reads (25%) | catalogued as rs1459415150; called by muse, mutect2, varscan2
- DNMT1 | c.3108C>T p.H1036= | Silent (SNP) | VAF 106/430 reads (25%) | catalogued as rs141856197; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EHBP1 | c.1428A>G p.L476= | Silent (SNP) | VAF 81/276 reads (29%) | called by muse, mutect2, varscan2
- FBN3 | c.6234G>A p.P2078= | Silent (SNP) | VAF 113/427 reads (26%) | catalogued as rs772743589; called by muse, mutect2, varscan2
- HYDIN | c.6486C>T p.S2162= | Silent (SNP) | VAF 50/244 reads (20%) | catalogued as rs201229423; called by muse, mutect2, varscan2
- IZUMO4 | c.33G>A p.T11= | Silent (SNP) | VAF 102/497 reads (21%) | catalogued as COSV100642754, COSV100643115, COSV61433378; called by muse, mutect2, varscan2
- LOXHD1 | c.1950C>T p.N650= | Silent (SNP) | VAF 59/247 reads (24%) | catalogued as rs371762941; ClinVar: likely benign; called by muse, mutect2, varscan2
- MNDA | c.336G>A p.A112= | Silent (SNP) | VAF 76/406 reads (19%) | catalogued as rs780583002, COSV63740866; called by muse, mutect2, varscan2
- MYH2 | c.3459C>T p.S1153= | Silent (SNP) | VAF 46/398 reads (12%) | catalogued as rs142095822; called by muse, mutect2, varscan2
- ZDHHC11B | c.153C>T p.G51= | Silent (SNP) | VAF 163/661 reads (25%) | catalogued as rs762369299, COSV66978013; called by muse, mutect2, varscan2
